Surgical pathology report (de-identified scan), TCGA case TCGA-PL-A8LX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Institute of Human Virology Nigeria, specimen TCGA-PL-A8LX-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Tissue Source Site (TSS):

Date of Tumour Procurement:

ICD: 0.3
Carcinoma, infiltrating duct
8500/3
Site: @ Breast NOS
Q50.9
7/5/14/14

1. **GROSS ASSESSMENT:** Cut section showed a variegated tumour.

2. MICROSCOPIC ASSESSMENT

Microscopic description: Section shows an invasive tumour growing solid nests, cords, comedo and tubular patterns.. It is composed of large cells having moderately pleomorphic hyperchromatic nuclei and amphophilic cytoplasm. The stroma is desmoplastic containing similar tumour cells and lymphocytes. Focal areas of necrosis noted.

3. **Tumour Type:** Malignant

4. **Tumour Site:** Left Breast

5. **Distance of invasive carcinoma to closest margin:** 5mm

- **Which margin?** Deep resection

[page 2 of 2]
TSS Unique patient ID:

6. HISTOLOGICAL DIAGNOSIS: Invasive ductal carcinoma

7. COMMENTS:

Dr

Reporting Pathologist Name

Signature

Date

Prior T. Malignancy History		✓
Case is (Unique)	SC	11/14/13

Source: NCI Genomic Data Commons file 6cbe19af-a079-4ca6-afe6-26ea690c40f2 (TCGA-PL-A8LX.E6DD0840-4D71-4EEC-B559-F6BFC9E7E68B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).